Surgical pathology report (de-identified scan), TCGA case TCGA-19-1386, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-1386-01A (Primary Tumor).

[page 1 of 2]
Gender: M

DOB: [REDACTED]

Age: [REDACTED]

Phone: [REDACTED]

Address: [REDACTED]

Result Detail

Pathology Result: [REDACTED]

Specimen Collected Date: [REDACTED]

Order Number: [REDACTED]

Ordering Provider: [REDACTED]

Medical Record Number: [REDACTED]

Facility: [REDACTED]

Status: C

Accession #: [REDACTED] Date of Procedure: [REDACTED]

Pathologist: [REDACTED]

Date Reported: [REDACTED]

Date Received: [REDACTED]

Submitting Physician: [REDACTED] Amended Report

Addendum Present

FINAL DIAGNOSIS

A. B. C, D: TUMOR, LEFT TEMPORAL, RESECTION:

--GLIOBLASTOMA, SMALL CELL SUBTYPE. SEE NOTE.

Note: This cellular infiltrating glioblastoma demonstrates foci of necrosis and microvascular proliferation. Tumor cells are positive for GFAP immunostain.

KI-67 immunostain highlights scattered cells.

Immunostain for SMI31 and synaptophysin were used in the evaluation.

Immunostain for EGFR and FISH for lp19q are pending and will be reported in the addendum.

Note

One or more of the reagents used to perform assays on this specimen MAY have contained components considered to be analyte specific reagents (ASR's).

ASR's

have not been cleared or approved by the U.S. Food and Drug Administration.

These assays were developed and their performance characteristics determined by the Department of Pathology at [REDACTED] The assays

were performed with appropriate positive and negative controls.

Electronically Signed Out By [REDACTED]

Amendment Comments:

Amended: [REDACTED]

Reason: Additional Pathology Material

Amended to include part D final diagnosis which was inadvertently omitted.

Previous Signout Date: [REDACTED]

Intraoperative Consult Diagnosis

A: Microscopic: Brain biopsy: Nondiagnostic specimen consisting of slightly hypercellular cortex. [REDACTED]

B: Microscopic: Brain lesion biopsy: Suspicious for infiltrating glioma (one mitoses found).

C: Microscopic: Brain tumor biopsy: Consistent with high grade glioma (GBM).

Addendum/Procedures:

Addendum Date Ordered: [REDACTED]

Status: Signed Out

Date Complete: [REDACTED]

Date Reported: [REDACTED]

Addendum Diagnosis

IMMUNOSTAIN FOR EGFR IS STRONGLY AND DIFFUSELY POSITIVE IN THE TUMOR SUPPORTING THE DIAGNOSIS OF GLIOBLASTOMA, SMALL CELL VARIANT.

[page 2 of 2]
Electronically Signed Out By [REDACTED]
Addendum Date Ordered: [REDACTED] Status: Signed Out
Date Complete: [REDACTED]
Date Reported: [REDACTED]

Addendum Diagnosis

BY THE REQUEST OF THE CLINICIAN OR THE PATIENT THIS CASE WAS SENT TO [REDACTED]
[REDACTED] FOR REVIEW.

[REDACTED] REPORT FROM [REDACTED] STATES:
LEFT TEMPORAL LOBE, EXCISION- GLIOBLASTOMA MULTIFORME, SMALL CELL TYPE, WHO
GRADE IV.

COMPLETE [REDACTED] REPORT IS KEPT ON FILE IN THE DEPARTMENT OF PATHOLOGY.
FISH FOR 1P/19Q AND EGFR WAS PERFORMED AT [REDACTED] WITH THE
FOLLOWING RESULTS:

CHROMOSOME 1P - INTACT
CHROMOSOME 19Q - INTACT
EGFR - AMPLIFIED.

COMPLETE [REDACTED] REPORT IS KEPT ON FILE IN THE DEPARTMENT OF
PATHOLOGY.

Electronically Signed Out By [REDACTED]

Clinical History:

Glioma

Specimens Submitted As:

- A: TUMOR LEFT TEMPORAL NODE
- B: LEFT TEMPORAL TUMOR
- C: LEFT TEMPORAL TUMOR
- D: LEFT TEMPORAL TUMOR

Gross Description:

A: Received fresh for intraoperative consultation, labelled with the
patient's

name and number, is a piece of pink-tan, soft tissue, 0.4 x 0.4 x 0.3 cm. The
specimen is submitted entirely in two cassettes.

B: Received fresh for intraoperative consultation, labelled with the
patient's

name and hospital number, and "left temporal tumor", is an irregular
fragment

of tan-white brain tissue, 0.6 x 0.5 x 0.3 cm. A touch imprint was made.

Representative sections are submitted for two frozen sections. The specimen is
entirely submitted in three cassettes.

C: Received fresh for intraoperative consultation, labelled with the
patient's

name and hospital number, are multiple, irregular fragments of tan-red, soft
tissue, 1.3 x 1.2 x 0.5 cm in aggregate. A portion of this tissue is used to
make touch preparation. A portion of this tissue is submitted for frozen
section. The tissue is submitted entirely in two cassettes.

D: Received fresh, post fixed in formalin, labeled with the patient's name,
number, and "tumor", are multiple tan to brown irregular soft tissue
fragments

ranging from flecks to 1.7 x 0.8 x 0.7 cm. The largest fragment is bisected.
Submitted entirely in 3 cassettes.

Summary of Cassettes:

- A 1FS
- 2 remainder of tissue
- B 1,2 representative sections from frozen section
- 3 remainder of tissue
- C 1FS
- 2 remainder of specimen
- D 1 bisected fragment
- 2,3 remainder of specimen

Source: NCI Genomic Data Commons file 53dfbf1a-e491-4cca-bed5-c04e3888aaa2 (TCGA-19-1386.F3877FA4-E6E5-4666-B9FB-A4AF91A5DA63.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).